Surgical pathology report (de-identified scan), TCGA case TCGA-FA-A82F, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Asterand, specimen TCGA-FA-A82F-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumor is located in Small intestine, moderately-margin, soft, solid, or yellow, gray surface with 6x5x3cm in size. Three mesenteric masses are 0.5x2cm.

Microscopic Description: Mucosa is ulcerated. Tumor cells arrange in diffuse replace benign tissue. The tumor cells are composed of large transformed lymphoid cells with hyperchromatic enlarged nuclei. Tumor cells are oval or round in shape with defined cytoplasm. Nucleoli is single or multiple. Mitotic figures are common.

Diagnosis Details: Large B-cell diffuse lymphoma

Comments:

Formatted Path Reports: Small intestine tumor checklist

Diagnosis: Diffuse large B-cell lymphoma of the small intestine

IHC Results: CD20(+), CD3(-), CKAE1/AE3(-)

Extranodal involvement : Small intestine, mesenteric lymph node

Neo-adjuvant treatment: No

Comments: None

ICD-O-3
Diffuse large B-cell lymphoma NOS
9680/3
Site: Small intestine NOS
C17.9
JY 10/30/13

Reviewed Initials	Kmt	

Source: NCI Genomic Data Commons file c9108525-9dc2-40a1-bf31-8200484d4f40 (TCGA-FA-A82F.9BDF3D5C-8203-4F43-9BE5-8F1F278C124B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).